Somatic mutation profile of tumor specimen TCGA-DJ-A13O-01A (aliquot TCGA-DJ-A13O-01A-11D-A10S-08) from TCGA case TCGA-DJ-A13O, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 56.9 years (20,779 days).
Specimen TCGA-DJ-A13O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b344d9d-ed66-43f7-a9b1-1541a4c86915.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A13O-10A (Blood Derived Normal), aliquot TCGA-DJ-A13O-10A-01D-A10S-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8adf4895-6044-4600-ba6a-6dcf78f766cd

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ANAPC5 | c.1165G>A p.A389T | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV55844096; called by muse, mutect2, varscan2
- KCNK1 | c.119T>A p.V40D | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV64039085; called by muse, mutect2, varscan2
- PRICKLE1 | c.740A>G p.Y247C | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61544913; called by muse, mutect2, varscan2
- BRD8 | c.642+540C>T | Intron (SNP) | VAF 7/61 reads (11%) | catalogued as COSV50159806; called by muse, mutect2
